Somatic mutation profile of tumor specimen HCM-WCMC-0504-C18-01A (aliquot HCM-WCMC-0504-C18-01A-11D-A83U-36) from HCMI case HCM-WCMC-0504-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G4; Age at diagnosis: 58.6 years (21,389 days).
Specimen HCM-WCMC-0504-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d723520e-3703-423e-ac43-028c4749ee30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0504-C18-10B (Blood Derived Normal), aliquot HCM-WCMC-0504-C18-10B-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fcf98b0-1d6e-43a7-923e-5a4f8f567550

The open-access MAF lists 1,197 somatic variants for this specimen: 893 protein-altering or splice-affecting, 253 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 638, Silent 253, Frame Shift Del 165, Frame Shift Ins 37, Nonsense Mutation 30, Intron 25, 3'UTR 11, Splice Region 10, In Frame Del 8, 5'Flank 8, 3'Flank 3, Splice Site 3.

Variants (750 of 1,197; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 220/1396 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.945); catalogued as rs730880056; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 222/1376 reads (16%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DMD | c.10453del p.L3485* | Frame Shift Del (DEL) | VAF 210/1542 reads (14%) | catalogued as rs886043375, CD073610; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPHS1 | c.3554dup p.S1186Vfs*10 | Frame Shift Ins (INS) | VAF 149/970 reads (15%) | catalogued as rs750714387; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AARD | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 262/2086 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs542421964, COSV65599658; called by muse, varscan2
- ABCC2 | c.4085G>T p.G1362V | Missense Mutation (SNP) | VAF 163/1127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64987105; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 201/1464 reads (14%) | SIFT deleterious, low confidence (0); catalogued as rs773242958, COSV99865371; called by muse, mutect2, varscan2
- AC004997.1 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 157/1186 reads (13%) | SIFT deleterious, low confidence (0.03); catalogued as rs574213079; called by muse, mutect2, varscan2
- AC011462.1 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 218/1313 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as rs761915209; called by muse, mutect2, varscan2
- ACTRT2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 128/695 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs189197365; called by muse, mutect2, varscan2
- ACVR2B | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 240/1584 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1241037610, COSV61702516; called by muse, varscan2
- ADAMTS10 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 226/1367 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs111234410; called by muse, mutect2, varscan2
- ADAMTS3 | c.1067del p.L356* | Frame Shift Del (DEL) | VAF 163/1107 reads (15%) | catalogued as rs1424429467; called by mutect2, pindel, varscan2
- ADARB2 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 172/1228 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs144565549; called by muse, mutect2, varscan2
- ADARB2 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 305/2119 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1322029552, COSV67228331; called by muse, mutect2, varscan2
- ADGRA3 | c.3211C>T p.Q1071* | Nonsense Mutation (SNP) | VAF 216/1437 reads (15%) | catalogued as rs1433768320; called by muse, mutect2, varscan2
- ADGRB3 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 132/1080 reads (12%) | catalogued as COSV65402251; called by muse, varscan2
- ADNP | c.2594del p.K865Sfs*49 | Frame Shift Del (DEL) | VAF 203/1280 reads (16%) | catalogued as COSV100823746; called by mutect2, pindel, varscan2
- ADSS2 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 113/984 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs150012791; called by muse, mutect2, varscan2
- AGRN | c.5416C>T p.R1806W | Missense Mutation (SNP) | VAF 252/1602 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs757150379; called by muse, mutect2, varscan2
- AK8 | c.176G>T p.R59M | Missense Mutation (SNP) | VAF 133/944 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV53761217, COSV53761951; called by muse, mutect2, varscan2
- ALPI | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 201/1848 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.542); catalogued as rs750554208; called by muse, mutect2, varscan2
- ANGPTL2 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 184/1300 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); catalogued as rs760636806; called by muse, mutect2, varscan2
- ANGPTL7 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 224/1511 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100815977; called by muse, mutect2, varscan2
- AP3B2 | c.2710A>G p.S904G (on ENST00000261722; = p.S898G on NM_004644.5) | Missense Mutation (SNP) | VAF 191/1186 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1257261195; called by muse, mutect2, varscan2
- APCDD1L | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 70/2836 reads (2%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs914247688; called by muse, mutect2
- APEH | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 138/926 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs774564457; called by muse, mutect2, varscan2
- AQP2 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 180/1250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52229740; called by muse, mutect2, varscan2
- AR | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 226/1660 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as rs962089572; called by muse, varscan2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 138/1206 reads (11%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- ARFGEF2 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 214/1519 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs748227723, COSV64212843; called by muse, mutect2, varscan2
- ARHGAP20 | c.630+1G>A p.X210_splice | Splice Site (SNP) | VAF 106/663 reads (16%) | catalogued as rs1449319024, COSV52814832; called by muse, mutect2, varscan2
- ARHGEF10 | c.2197G>A p.V733M (on ENST00000398564; = p.V708M on NM_014629.4) | Missense Mutation (SNP) | VAF 203/1692 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as rs769602938; called by muse, mutect2, varscan2
- ARHGEF11 | c.4151dup p.Q1385Sfs*3 | Frame Shift Ins (INS) | VAF 192/1437 reads (13%) | catalogued as rs1423067261; called by mutect2, pindel, varscan2
- ARHGEF15 | c.1366del p.R456Vfs*21 | Frame Shift Del (DEL) | VAF 277/1788 reads (15%) | catalogued as rs1567676744; called by mutect2, pindel, varscan2
- ARSL | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 213/1417 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.376); catalogued as rs761135869; called by muse, mutect2, varscan2
- ARVCF | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 347/2100 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs759894174, COSV99599298; called by muse, mutect2, varscan2
- ARVCF | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 374/2187 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as rs374797711; called by muse, mutect2, varscan2
- ASXL1 | c.3806C>T p.S1269L | Missense Mutation (SNP) | VAF 279/1794 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as rs747065583, COSV60109567; called by muse, mutect2, varscan2
- ASXL2 | c.4285G>A p.V1429I | Missense Mutation (SNP) | VAF 139/1057 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754392619, COSV55464427; called by muse, mutect2, varscan2
- ATM | c.7223C>T p.S2408L | Missense Mutation (SNP) | VAF 189/1240 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs730881315, COSV53738904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.713del p.G238Efs*60 | Frame Shift Del (DEL) | VAF 157/1034 reads (15%) | catalogued as COSV63111162; called by mutect2, varscan2
- ATP6V1B1 | c.1251C>T p.Y417= | Splice Region (SNP) | VAF 142/895 reads (16%) | catalogued as rs1426120425, CM135387; called by muse, mutect2, varscan2
- AVPR1A | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 240/1676 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV54548053; called by muse, mutect2, varscan2
- B3GNT9 | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 304/1605 reads (19%) | catalogued as rs371081032; called by muse, mutect2, varscan2
- BAHCC1 | c.4541C>T p.A1514V | Missense Mutation (SNP) | VAF 191/1399 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as rs1294495291, COSV57026991; called by muse, mutect2, varscan2
- BATF2 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 284/1716 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs1347786641; called by muse, mutect2, varscan2
- BCOR | c.4261C>T p.R1421C (on ENST00000378444 / NM_001123385.2; = p.R1387C on NM_017745.6) | Missense Mutation (SNP) | VAF 343/2263 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); catalogued as rs746716983, COSV60712517; called by muse, mutect2, varscan2
- BCS1L | c.1008G>A p.R336= | Splice Region (SNP) | VAF 143/840 reads (17%) | catalogued as rs1314813758; called by muse, mutect2, varscan2
- BICRA | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 274/1665 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs868510387; called by muse, mutect2, varscan2
- BMP7 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 154/1140 reads (14%) | catalogued as rs769591631; called by muse, mutect2, varscan2
- BMP7 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 196/1416 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs776230892, COSV67782177; called by muse, mutect2, varscan2
- BMP8B | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 179/1841 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs766684364; called by muse, mutect2, varscan2
- BOP1 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 391/2799 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.039); catalogued as rs1027468097; called by muse, mutect2, varscan2
- BTBD19 | c.130G>C p.A44P | Missense Mutation (SNP) | VAF 202/1360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1271408937; called by muse, mutect2, varscan2
- C15orf62 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 288/1850 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1456080294; called by muse, mutect2, varscan2
- C17orf107 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 162/1198 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.678); catalogued as rs763019934; called by muse, varscan2
- C17orf107 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 290/2214 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1186314661, COSV53419313; called by muse, mutect2
- C4A | c.3574G>A p.A1192T | Missense Mutation (SNP) | VAF 323/3255 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); catalogued as rs759121287, COSV71177765; called by muse, mutect2, varscan2
- C6orf47 | c.481del p.E161Nfs*22 | Frame Shift Del (DEL) | VAF 400/2811 reads (14%) | catalogued as rs1396655057; called by mutect2, pindel, varscan2
- CACNA1S | c.5218C>A p.P1740T | Missense Mutation (SNP) | VAF 126/855 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.081); catalogued as COSV62944939; called by muse, varscan2
- CAND2 | c.3260G>A p.R1087Q (on ENST00000456430 / NM_001162499.2; = p.R970Q on NM_012298.3) | Missense Mutation (SNP) | VAF 179/1193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781451160, COSV55990798; called by muse, mutect2, varscan2
- CASP8 | c.1380del p.K461Nfs*10 (on ENST00000432109 / NM_033355.3; = p.K478Nfs*10 on NM_001228.4) | Frame Shift Del (DEL) | VAF 240/1593 reads (15%) | catalogued as COSV51859087; called by mutect2, pindel, varscan2
- CCDC151 | c.747C>A p.D249E | Missense Mutation (SNP) | VAF 158/1117 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs1229956522; called by muse, mutect2, varscan2
- CCDC40 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 296/1864 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376363442; ClinVar: uncertain significance; called by muse, mutect2
- CCDC54 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 161/1139 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1267316139; called by muse, mutect2, varscan2
- CCDC85A | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 331/2141 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs760317264; called by muse, mutect2, varscan2
- CCNA1 | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 94/560 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV55222951; called by muse, mutect2, varscan2
- CD248 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 287/1791 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs146691747; called by muse, mutect2, varscan2
- CD300LG | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 171/1018 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs373605771, COSV99517330; called by muse, mutect2, varscan2
- CDC123 | c.404A>G p.K135R | Missense Mutation (SNP) | VAF 133/933 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760876745; called by muse, mutect2, varscan2
- CDCA7 | c.571C>A p.L191I (on ENST00000347703 / NM_145810.3; = p.L270I on NM_031942.5) | Missense Mutation (SNP) | VAF 200/1461 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100143807; called by muse, mutect2, varscan2
- CDH13 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 149/1099 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs771595136; called by muse, mutect2, varscan2
- CDH4 | c.1781del p.P594Rfs*35 | Frame Shift Del (DEL) | VAF 192/1135 reads (17%) | catalogued as rs1367432489; called by mutect2, pindel, varscan2
- CDH6 | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 235/1611 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746180154; called by muse, mutect2, varscan2
- CDK10 | c.935C>T p.A312V (on ENST00000353379 / NM_052988.5; = p.A241V on NM_052987.4) | Missense Mutation (SNP) | VAF 188/1070 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs780139658; called by muse, mutect2, varscan2
- CDK5R2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 297/1869 reads (16%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.448); catalogued as rs1429667871; called by muse, mutect2, varscan2
- CECR2 | c.703T>C p.S235P (on ENST00000342247 / NM_001290047.2; = p.S72P on NM_001290046.1) | Missense Mutation (SNP) | VAF 131/771 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs1353859755; called by muse, mutect2, varscan2
- CELSR3 | c.5381G>A p.R1794Q | Missense Mutation (SNP) | VAF 303/1761 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1028524336; called by muse, mutect2, varscan2
- CEP131 | c.1721T>C p.M574T (on ENST00000269392 / NM_001319228.2; = p.M571T on NM_014984.4) | Missense Mutation (SNP) | VAF 240/1518 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs762629509; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 79/598 reads (13%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 182/1141 reads (16%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CHD3 | c.3124T>C p.S1042P | Missense Mutation (SNP) | VAF 137/731 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as COSV100391133; called by muse, mutect2, varscan2
- CHD8 | c.7337C>T p.T2446M (on ENST00000646647 / NM_001170629.2; = p.T2167M on NM_020920.4) | Missense Mutation (SNP) | VAF 218/1542 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.105); catalogued as rs763909898; called by muse, mutect2, varscan2
- CHERP | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 448/2589 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs775337450; called by muse, mutect2, varscan2
- CHERP | c.21del p.D8Mfs*26 | Frame Shift Del (DEL) | VAF 310/1930 reads (16%) | catalogued as COSV99550254; called by mutect2, pindel, varscan2
- CIC | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 351/2068 reads (17%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.137); catalogued as rs1201027582; called by muse, mutect2, varscan2
- CILP2 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 282/1918 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs137977776; called by muse, varscan2
- CLCN6 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 277/1697 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56740416; called by muse, mutect2, varscan2
- CLDN18 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 166/1119 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs756497056; called by muse, mutect2, varscan2
- CLMN | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 166/1151 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.232); catalogued as rs145924471; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 162/1224 reads (13%) | catalogued as rs758841384; called by pindel, varscan2
- CNDP2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 180/1290 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs200600524; called by muse, mutect2
- CNTNAP1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 192/1123 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV52848213; called by muse, mutect2, varscan2
- COL27A1 | c.1911T>C p.G637= | Splice Region (SNP) | VAF 130/895 reads (15%) | catalogued as rs1272426516; called by muse, varscan2
- COL4A3 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 157/1132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67420154; called by muse, mutect2, varscan2
- COL7A1 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 152/967 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs868465415, COSV60391056; called by muse, mutect2, varscan2
- COPS6 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 144/1067 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); catalogued as COSV100385164; called by muse, mutect2, varscan2
- CPZ | c.1024C>T p.R342C (on ENST00000360986 / NM_001014447.3; = p.R331C on NM_003652.3) | Missense Mutation (SNP) | VAF 238/1584 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755742622, COSV100248635; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 106/882 reads (12%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRELD2 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 282/1890 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1423277655; called by mutect2, varscan2
- CRISPLD1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 99/1006 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.292); catalogued as COSV51547938; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 79/616 reads (13%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CSF1R | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 187/1261 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1318254419, COSV53831916; called by muse, mutect2, varscan2
- CTNND2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 220/1569 reads (14%) | catalogued as COSV100479151; called by muse, mutect2, varscan2
- CUEDC1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 302/1727 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327648739; called by muse, mutect2, varscan2
- CUX2 | c.4420C>T p.R1474W | Missense Mutation (SNP) | VAF 141/1052 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55628641; called by muse, mutect2, varscan2
- CXCR2 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 170/1225 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199777583; called by muse, mutect2, varscan2
- DACT3 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 432/2485 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs552110358; called by muse, mutect2, varscan2
- DAGLB | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 160/1127 reads (14%) | catalogued as rs562661517, CM142359; called by muse, mutect2, varscan2
- DBNDD2 | c.562del p.Q188Sfs*12 | Frame Shift Del (DEL) | VAF 209/1436 reads (15%) | catalogued as rs1320987043; called by mutect2, pindel, varscan2
- DCAF12L2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 232/1769 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.271); catalogued as COSV63580171; called by muse, mutect2, varscan2
- DCHS2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 333/2002 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311246649, COSV100253150; called by muse, mutect2, varscan2
- DDX43 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 275/1744 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.057); catalogued as COSV100946233; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 99/463 reads (21%) | catalogued as rs778036194; called by mutect2, varscan2
- DIAPH3 | c.973dup p.C325Lfs*29 (on ENST00000400324 / NM_001042517.2; = p.C62Lfs*29 on NM_030932.3) | Frame Shift Ins (INS) | VAF 100/742 reads (13%) | catalogued as rs766969544; called by mutect2, varscan2
- DIPK1C | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 263/1718 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs762337921; called by muse, mutect2, varscan2
- DIPK2A | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 232/1489 reads (16%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.855); catalogued as rs1235739562; called by muse, mutect2, varscan2
- DISP1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 127/876 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as rs765609888, COSV52657862; called by muse, mutect2, varscan2
- DLGAP2 | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 278/2310 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV70096210; called by muse, mutect2, varscan2
- DLX5 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 279/1810 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV99756721; called by muse, mutect2, varscan2
- DLX5 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 161/1111 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as rs1460070802; called by muse, mutect2, varscan2
- DNAH1 | c.9122G>A p.R3041H | Missense Mutation (SNP) | VAF 216/1598 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs546452557, COSV101326364; called by muse, mutect2, varscan2
- DNAH14 | c.8143G>A p.A2715T (on ENST00000445597; = p.A3518T on NM_001367479.1) | Missense Mutation (SNP) | VAF 204/1346 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as rs369673460, COSV99071038; called by muse, mutect2, varscan2
- DNAH17 | c.4076G>A p.R1359Q | Missense Mutation (SNP) | VAF 189/1188 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375265574; called by muse, mutect2, varscan2
- DOT1L | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 220/1479 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs781606489, COSV67107693; called by muse, mutect2, varscan2
- DPY19L1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 101/814 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs200098469, COSV60584869; called by muse, mutect2, varscan2
- DTX2 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 290/2336 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs199598165; called by muse, varscan2
- DUOX1 | c.4568dup p.G1524Wfs*26 | Frame Shift Ins (INS) | VAF 235/1566 reads (15%) | catalogued as rs751561010; called by mutect2, pindel, varscan2
- DYNC1I1 | c.1566_1568del p.N522del | In Frame Del (DEL) | VAF 120/652 reads (18%) | catalogued as rs779190112; called by pindel, varscan2
- E2F2 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 113/679 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764211496; called by muse, varscan2
- EBF2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 140/1074 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV68775824; called by muse, mutect2, varscan2
- ECPAS | c.3983C>T p.A1328V | Missense Mutation (SNP) | VAF 101/835 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs1263750941; called by muse, mutect2, varscan2
- EFR3A | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 117/895 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs536114379; called by muse, mutect2, varscan2
- EIF2B3 | c.508A>G p.M170V | Missense Mutation (SNP) | VAF 178/1096 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV64518863; called by muse, mutect2, varscan2
- EIF4G3 | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 134/1022 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51694889; called by muse, mutect2, varscan2
- ELAVL3 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 298/1826 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as rs748019175; called by muse, mutect2, varscan2
- ELP4 | c.747del p.K249Nfs*6 (on ENST00000350638; = p.K248Nfs*6 on NM_019040.5) | Frame Shift Del (DEL) | VAF 84/591 reads (14%) | catalogued as COSV63351931; called by mutect2, pindel, varscan2
- EMILIN2 | c.2767G>A p.V923I | Missense Mutation (SNP) | VAF 158/1234 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); catalogued as rs780356221, COSV99598141; called by muse, mutect2, varscan2
- EPHB6 | c.2639G>A p.R880Q | Missense Mutation (SNP) | VAF 217/1356 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291135944, COSV100844294; called by muse, mutect2, varscan2
- EPS15 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 112/904 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs930419380; called by muse, mutect2, varscan2
- ERCC2 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 245/1714 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs768677952, COSV67263648; called by muse, mutect2, varscan2
- ETV5 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 231/1582 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV60506181; called by muse, mutect2, varscan2
- EVL | c.874_876del p.K292del (on ENST00000402714 / NM_001330221.2; = p.K294del on NM_016337.3) | In Frame Del (DEL) | VAF 178/1310 reads (14%) | catalogued as rs1200397092; called by pindel, varscan2
- EYA1 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 85/787 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.123); catalogued as rs145219836, COSV58158058; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 131/1121 reads (12%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM131A | c.768del p.S257Afs*48 (on ENST00000310585; = p.S288Afs*48 on NM_144635.5) | Frame Shift Del (DEL) | VAF 281/1849 reads (15%) | catalogued as COSV55602091; called by mutect2, varscan2
- FAM47C | c.2167G>A p.V723I | Missense Mutation (SNP) | VAF 221/1444 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs782084099; called by muse, mutect2, varscan2
- FAM78B | c.692del p.P231Lfs*4 | Frame Shift Del (DEL) | VAF 176/1438 reads (12%) | catalogued as rs763715884; called by mutect2, pindel, varscan2
- FAM83H | c.2787dup p.V930Rfs*41 | Frame Shift Ins (INS) | VAF 333/2302 reads (14%) | catalogued as rs781931295; called by mutect2, varscan2
- FARP1 | c.2888_2890del p.F963del | In Frame Del (DEL) | VAF 126/976 reads (13%) | catalogued as rs1390774650; called by pindel, varscan2
- FBRSL1 | c.2874del p.A959Pfs*45 | Frame Shift Del (DEL) | VAF 236/1559 reads (15%) | catalogued as rs893226416; called by mutect2, pindel, varscan2
- FEM1A | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 278/1776 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.108); catalogued as rs146137689; called by muse, varscan2
- FGF14 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 286/2074 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs750276006, COSV65945025; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 182/1282 reads (14%) | catalogued as rs777980924; called by mutect2, varscan2
- FLG | c.3685G>A p.G1229S | Missense Mutation (SNP) | VAF 135/788 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs377533309, COSV100911121; called by muse, mutect2, varscan2
- FLNA | c.5098G>A p.V1700M (on ENST00000369850 / NM_001110556.2; = p.V1692M on NM_001456.3) | Missense Mutation (SNP) | VAF 258/1597 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782351877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXF2 | c.919_921dup p.D307dup | In Frame Ins (INS) | VAF 282/1340 reads (21%) | catalogued as rs1200364411; called by pindel, varscan2
- FOXQ1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 243/1670 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1256631452, COSV57259630; called by muse, mutect2, varscan2
- FRMPD4 | c.1857G>T p.E619D | Missense Mutation (SNP) | VAF 299/1735 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.047); catalogued as COSV101041737; called by muse, mutect2, varscan2
- FYTTD1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 115/907 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs761860704, COSV54084497; called by muse, mutect2, varscan2
- FZD9 | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 244/1579 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1189855467; called by muse, mutect2, varscan2
- GALNT16 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 118/1045 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778928386; called by muse, mutect2, varscan2
- GDAP1L1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 149/971 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs750968488, COSV100697527, COSV61158883; called by muse, mutect2, varscan2
- GNRH2 | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 247/1749 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55662251; called by muse, mutect2, varscan2
- GPATCH8 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 242/1507 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs749705021; called by muse, mutect2, varscan2
- GPR37 | c.357del p.W120Gfs*51 | Frame Shift Del (DEL) | VAF 233/1782 reads (13%) | catalogued as COSV58258793; called by mutect2, pindel, varscan2
- GRAMD4 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 178/1258 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1208069675; called by muse, mutect2, varscan2
- GRM1 | c.446del p.P149Qfs*11 | Frame Shift Del (DEL) | VAF 175/1382 reads (13%) | catalogued as rs1207726214, COSV51123015, COSV99267293; called by pindel, varscan2
- GRM7 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 121/837 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs1025403472, COSV100735833, COSV63173475, COSV99066173; called by muse, varscan2
- GYG2 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 309/2196 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs147564323; called by muse, mutect2, varscan2
- HAP1 | c.1536G>A p.M512I (on ENST00000310778 / NM_001367460.1; = p.M460I on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/1098 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781860680; called by muse, mutect2
- HAPLN4 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 441/2534 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as rs1442894214; called by muse, mutect2, varscan2
- HGS | c.1447del p.A483Rfs*2 | Frame Shift Del (DEL) | VAF 278/1856 reads (15%) | catalogued as rs1555699517, COSV100230656; called by mutect2, pindel, varscan2
- HMCN1 | c.6229G>A p.D2077N | Missense Mutation (SNP) | VAF 167/975 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144448119; called by muse, mutect2, varscan2
- HOXC13 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 366/2301 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1470777937; called by muse, mutect2, varscan2
- HS6ST2 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 305/2297 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV63718366; called by muse, mutect2, varscan2
- HSPA1L | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 177/1306 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs375290879; called by muse, mutect2, varscan2
- HSPG2 | c.1834G>T p.G612C | Missense Mutation (SNP) | VAF 223/1540 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768946900; called by muse, mutect2, varscan2
- HUWE1 | c.8516C>T p.A2839V | Missense Mutation (SNP) | VAF 172/1055 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as COSV53341138; called by muse, mutect2, varscan2
- HYDIN | c.4232C>T p.T1411M | Missense Mutation (SNP) | VAF 92/809 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs763237651, COSV66830824; called by muse, mutect2, varscan2
- IGF2R | c.2660C>T p.T887M | Missense Mutation (SNP) | VAF 201/1217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752875889; called by muse, mutect2, varscan2
- IGHV5-51 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 184/1275 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs1555541242; called by muse, mutect2, varscan2
- IHH | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 300/1907 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs3731880; called by muse, mutect2, varscan2
- IL17RC | c.2253_2254del p.R751Sfs*14 (on ENST00000295981 / NM_153461.4; = p.R665Sfs*14 on NM_032732.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 318/2044 reads (16%) | catalogued as rs752617588; called by pindel, varscan2
- IL31RA | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 132/1057 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV51681363; called by muse, mutect2, varscan2
- ING1 | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 223/1469 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58170934; called by muse, mutect2, varscan2
- INSM2 | c.1144del p.A382Pfs*9 | Frame Shift Del (DEL) | VAF 267/1924 reads (14%) | catalogued as COSV51898306; called by mutect2, pindel, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 55/536 reads (10%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQSEC3 | c.2854G>A p.E952K (on ENST00000538872 / NM_001170738.2; = p.E649K on NM_015232.1) | Missense Mutation (SNP) | VAF 284/1871 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs781815118; called by muse, mutect2, varscan2
- IRF4 | c.963del p.D322Tfs*62 | Frame Shift Del (DEL) | VAF 266/1899 reads (14%) | catalogued as COSV66705190; called by mutect2, pindel, varscan2
- ISL2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 197/1286 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs756779917; called by muse, mutect2, varscan2
- KCNH3 | c.1366C>A p.L456I | Missense Mutation (SNP) | VAF 301/1967 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57789911; called by muse, mutect2, varscan2
- KCNK15 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 347/2078 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs970735520; called by muse, mutect2, varscan2
- KCNN1 | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 187/1143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1338697202; called by muse, mutect2, varscan2
- KCNV1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 202/1712 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52085727; called by muse, mutect2, varscan2
- KHDC4 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 104/833 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs760168909, COSV100850749, COSV64164546; called by muse, varscan2
- KIAA2013 | c.1380del p.L461Cfs*74 | Frame Shift Del (DEL) | VAF 256/1674 reads (15%) | catalogued as COSV64860737; called by mutect2, pindel, varscan2
- KIDINS220 | c.5065A>G p.S1689G | Missense Mutation (SNP) | VAF 218/1552 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs749481172; called by muse, mutect2, varscan2
- KIF5B | c.1647dup p.R550Tfs*4 | Frame Shift Ins (INS) | VAF 195/1401 reads (14%) | catalogued as rs745430029; called by mutect2, pindel, varscan2
- KIT | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 187/1225 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as rs767174569, COSV55386928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHDC7B | c.362C>A p.A121E (on ENST00000395676; = p.A762E on NM_138433.5) | Missense Mutation (SNP) | VAF 401/2461 reads (16%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.057); catalogued as rs777583262; called by muse, mutect2, varscan2
- KLHL35 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 354/2122 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as rs759314666; called by muse, mutect2, varscan2
- KLHL41 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 118/929 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs868095411; called by muse, mutect2, varscan2
- KMT2B | c.4235del p.G1412Afs*10 | Frame Shift Del (DEL) | VAF 330/2310 reads (14%) | catalogued as rs34078597; called by mutect2, pindel, varscan2
- KRT74 | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 288/1906 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); catalogued as rs763304950, COSV99977475; called by muse, mutect2, varscan2
- KRTAP10-7 | c.388A>G p.S130G | Missense Mutation (SNP) | VAF 273/1847 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs233307, COSV59112209; called by muse, mutect2, varscan2
- KRTAP5-10 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 135/797 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as rs752243956, COSV64794097; called by muse, mutect2, varscan2
- KSR2 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 324/2012 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.46); catalogued as rs1022500773, COSV60392602; called by muse, varscan2
- LANCL3 | c.192del p.L65Ffs*129 | Frame Shift Del (DEL) | VAF 350/2111 reads (17%) | catalogued as rs782221297; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 128/982 reads (13%) | catalogued as COSV60222740; called by pindel, varscan2*
- LHX4 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 180/1198 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.316); catalogued as rs761944467, COSV99761922; called by muse, mutect2, varscan2
- LIN37 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 154/1091 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs374032128; called by muse, mutect2, varscan2
- LIPG | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 123/883 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM127990; called by muse, mutect2, varscan2
- LOXHD1 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 218/1554 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs916954027, COSV59662442; called by muse, varscan2
- LRFN2 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 245/1763 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs746243295, COSV57827102; called by muse, mutect2, varscan2
- LRP2 | c.10234G>A p.A3412T | Missense Mutation (SNP) | VAF 158/1144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147922851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC14 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 303/2236 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs745462286, COSV52883430; called by muse, mutect2, varscan2
- LRRCC1 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 144/1403 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as rs781467429; called by mutect2, varscan2
- LTA | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 259/1922 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.702); catalogued as rs377059622; called by muse, mutect2, varscan2
- LYST | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 149/1127 reads (13%) | catalogued as rs756867102, COSV67703931; called by muse, mutect2, varscan2
- MADD | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 200/1267 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs140505071; called by muse, mutect2, varscan2
- MAP3K5 | c.3667G>A p.V1223M | Missense Mutation (SNP) | VAF 155/1115 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as rs766760055, COSV62886601; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 201/1513 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs1254983501; called by muse, mutect2, varscan2
- MATN2 | c.1072del p.T358Rfs*5 | Frame Shift Del (DEL) | VAF 122/1252 reads (10%) | catalogued as rs1319426383; called by mutect2, pindel
- MBD2 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 83/769 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1242663921; called by muse, mutect2, varscan2
- MCOLN2 | c.747G>A p.T249= | Splice Region (SNP) | VAF 129/792 reads (16%) | catalogued as rs1377342424, COSV99393689; called by muse, mutect2, varscan2
- MED12 | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 175/1212 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV61354946; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 497/2105 reads (24%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MFAP2 | c.265C>G p.P89A | Missense Mutation (SNP) | VAF 194/1488 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs756106741, COSV100977637; called by muse, mutect2, varscan2
- MICU3 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 317/2503 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.024); catalogued as COSV58849276; called by muse, mutect2, varscan2
- MMP24 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 107/670 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1200868074; called by muse, mutect2, varscan2
- MROH6 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 446/3416 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs745639075; called by muse, mutect2
- MUC5B | c.3004G>A p.V1002M | Missense Mutation (SNP) | VAF 202/1383 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs764598061; called by muse, mutect2, varscan2
- MYB | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 121/837 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs777923027, COSV57196169, COSV57200862; called by muse, mutect2, varscan2
- MYO18A | c.3842G>A p.R1281Q | Missense Mutation (SNP) | VAF 149/1000 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs571276684; called by muse, mutect2, varscan2
- MYO5C | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 104/810 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs539722733, COSV55906722; called by muse, mutect2, varscan2
- MYOZ3 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 96/2588 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs766224195, COSV51739562; called by muse, mutect2
- NANOS3 | c.355G>A p.V119I (on ENST00000397555; = p.V138I on NM_001098622.2) | Missense Mutation (SNP) | VAF 314/1846 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs368073921; called by muse, varscan2
- NDUFAF7 | c.1048T>C p.S350P | Missense Mutation (SNP) | VAF 172/1261 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs993134186; called by muse, mutect2, varscan2
- NES | c.4610G>A p.G1537D | Missense Mutation (SNP) | VAF 272/1577 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV63960951; called by muse, mutect2, varscan2
- NFE2L3 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 170/1121 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs1408770675, COSV50227360; called by muse, mutect2, varscan2
- NKX6-2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 233/1509 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371870778; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 163/1125 reads (14%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NPAS3 | c.2317G>A p.A773T (on ENST00000356141 / NM_001164749.2; = p.A741T on NM_022123.3) | Missense Mutation (SNP) | VAF 164/1404 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs767138301; called by muse, mutect2, varscan2
- NPHP1 | c.1807G>T p.D603Y (on ENST00000393272 / NM_207181.4; = p.D604Y on NM_000272.5) | Missense Mutation (SNP) | VAF 116/712 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs772249010, COSV100338256, COSV104413681, COSV57211830; called by muse, mutect2, varscan2
- NPHP3 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 178/1048 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs889394540; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPHP4 | c.167G>A p.C56Y | Missense Mutation (SNP) | VAF 167/1150 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as rs865792284; called by muse, mutect2, varscan2
- NPRL2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 202/1570 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV99204563; called by muse, mutect2, varscan2
- NRXN3 | c.1856G>A p.R619H (on ENST00000335750 / NM_001330195.2; = p.R246H on NM_004796.6) | Missense Mutation (SNP) | VAF 211/1583 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752029799, COSV59717743; called by muse, mutect2, varscan2
- NT5C2 | c.370G>C p.G124R | Missense Mutation (SNP) | VAF 132/815 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100583307; called by muse, mutect2, varscan2
- NT5DC3 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 155/979 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs775554546; called by muse, mutect2, varscan2
- NXPE2 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 218/1589 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs1456654444; called by muse, mutect2, varscan2
- OR10G6 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 168/1129 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1007339903, COSV61022254; called by muse, mutect2, varscan2
- OR1E2 | c.80G>A p.C27Y | Missense Mutation (SNP) | VAF 164/1316 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs559638155; called by muse, mutect2, varscan2
- OR1N2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 158/985 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV65460257; called by muse, mutect2, varscan2
- OR2C1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 189/1180 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as rs780752599, COSV59240960; called by muse, mutect2, varscan2
- OR2T35 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 198/1516 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs542809469; called by muse, mutect2, varscan2
- OR4C6 | c.15C>A p.N5K | Missense Mutation (SNP) | VAF 71/565 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV100051636; called by muse, mutect2, varscan2
- OTOP1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 242/2332 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.229); catalogued as rs568093695, COSV99587842; called by muse, varscan2
- OVCH1 | c.277A>G p.S93G | Missense Mutation (SNP) | VAF 142/862 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs779763167; called by muse, mutect2, varscan2
- P2RY12 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 146/1036 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs763135685; called by muse, mutect2, varscan2
- PAK2 | c.1451A>G p.D484G | Missense Mutation (SNP) | VAF 121/984 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs761446581; called by muse, mutect2, varscan2
- PALMD | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 189/1254 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.207); catalogued as rs556174782, COSV54163638; called by muse, mutect2, varscan2
- PARD3 | c.1366del p.I456* | Frame Shift Del (DEL) | VAF 108/820 reads (13%) | catalogued as rs1484598500; called by mutect2, pindel, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 179/1389 reads (13%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PCDH17 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 186/1279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100932145; called by muse, mutect2, varscan2
- PCDHA1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 112/812 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as rs1446677911, COSV65374909; called by muse, mutect2, varscan2
- PCDHA5 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 286/2082 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as rs782637737; called by muse, mutect2, varscan2
- PCDHA7 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 205/1365 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as COSV65346505, COSV65348202; called by muse, mutect2, varscan2
- PCDHA7 | c.2156C>T p.T719M | Missense Mutation (SNP) | VAF 158/1112 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.1); catalogued as COSV100970845, COSV65335104; called by muse, mutect2, varscan2
- PCDHB2 | c.1685T>C p.F562S | Missense Mutation (SNP) | VAF 309/2454 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs1357663714; called by muse, mutect2, varscan2
- PCDHB8 | c.1150T>C p.C384R | Missense Mutation (SNP) | VAF 168/2704 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99176895; called by muse, mutect2
- PCDHGA3 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 162/1102 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as rs370532251, COSV53990751; called by muse, mutect2, varscan2
- PCDHGB1 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 216/1467 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV53959753; called by muse, mutect2, varscan2
- PCM1 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 142/1330 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746281426; called by muse, mutect2, varscan2
- PDE1C | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 129/829 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs775455105; called by muse, mutect2, varscan2
- PDE4DIP | c.6953T>C p.L2318P | Missense Mutation (SNP) | VAF 91/866 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553635563; called by muse, mutect2, varscan2
- PGS1 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 154/1055 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs368547832; called by muse, mutect2, varscan2
- PHKA2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 303/2087 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs774266693; called by muse, mutect2, varscan2
- PHLDA2 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 452/2616 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.099); catalogued as COSV56540919; called by muse, mutect2, varscan2
- PHLDB1 | c.3767G>A p.S1256N | Missense Mutation (SNP) | VAF 91/614 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs781845616; called by muse, mutect2, varscan2
- PHYKPL | c.1306A>G p.M436V | Missense Mutation (SNP) | VAF 166/1059 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1166151709; called by muse, mutect2, varscan2
- PHYKPL | c.1054dup p.I352Nfs*24 | Frame Shift Ins (INS) | VAF 188/1205 reads (16%) | catalogued as rs762471696; called by mutect2, pindel, varscan2
- PIP4K2C | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 120/660 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs543501661; called by muse, mutect2, varscan2
- PITPNM2 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 335/2205 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs376647562; called by muse, mutect2, varscan2
- PIWIL1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 135/987 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.186); catalogued as rs377411680; called by muse, mutect2, varscan2
- PLD3 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 160/920 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1017787217; called by muse, mutect2, varscan2
- PLEKHA7 | c.1726C>A p.P576T | Missense Mutation (SNP) | VAF 81/2130 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as rs1270157334; called by muse, mutect2
- PLEKHG3 | c.864G>A p.P288= (on ENST00000394691; = p.P344= on NM_001308147.2) | Splice Region (SNP) | VAF 152/842 reads (18%) | catalogued as rs1566706800, COSV55977532; called by muse, mutect2, varscan2
- PLEKHG5 | c.749C>T p.A250V (on ENST00000400915 / NM_001042663.3; = p.A213V on NM_020631.6) | Missense Mutation (SNP) | VAF 235/1500 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs367543633; ClinVar: uncertain significance; called by muse, varscan2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 144/1016 reads (14%) | catalogued as rs746342377; called by mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 269/1972 reads (14%) | catalogued as rs953293505; called by mutect2, pindel, varscan2
- PLXND1 | c.2767G>A p.V923M | Missense Mutation (SNP) | VAF 245/1706 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs762979740; called by muse, mutect2, varscan2
- PNCK | c.52C>T p.R18C (on ENST00000340888 / NM_001366975.1; = p.R101C on NM_001039582.3) | Missense Mutation (SNP) | VAF 284/1902 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs1349409547, COSV61744026; called by muse, varscan2
- POGK | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 200/1308 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs752253527, COSV63311164; called by muse, mutect2, varscan2
- POLG2 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 146/1259 reads (12%) | catalogued as rs782004592; called by muse, mutect2, varscan2
- POLN | c.212del p.K71Rfs*6 | Frame Shift Del (DEL) | VAF 112/755 reads (15%) | catalogued as rs760971697; called by mutect2, pindel, varscan2
- POU4F1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 182/1088 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.114); catalogued as rs763743520; called by muse, varscan2
- POU4F3 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 325/2036 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs148830499; called by muse, mutect2, varscan2
- PPP1CC | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 172/1188 reads (14%) | catalogued as rs866672821, COSV58582427; called by muse, varscan2
- PPP2R1A | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 328/2054 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs769334090, COSV59043773; called by muse, mutect2, varscan2
- PPP3CB | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 230/1410 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs758464886; called by muse, mutect2, varscan2
- PPP4R1 | c.2644C>T p.R882* (on ENST00000400556 / NM_001042388.3; = p.R865* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 72/1400 reads (5%) | catalogued as COSV53280295, COSV53280679; called by muse, mutect2
- PRAME | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 284/1854 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs1330513615; called by muse, mutect2, varscan2
- PRDM2 | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 216/1368 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs151171355, COSV52450854; called by muse, mutect2, varscan2
- PRDM6 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 192/1294 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1173169991, COSV68335207; called by muse, mutect2, varscan2
- PRDM9 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 116/1136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104393150; called by muse, mutect2, varscan2
- PRICKLE2 | c.567C>T p.C189= (on ENST00000295902; = p.C133= on NM_198859.4) | Splice Region (SNP) | VAF 152/877 reads (17%) | catalogued as rs764057934; called by muse, mutect2, varscan2
- PRKCG | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 271/1819 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1398372035; called by muse, mutect2, varscan2
- PRR5L | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 242/1611 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs780212600; called by muse, mutect2, varscan2
- PRRT2 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 189/1261 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as rs777959783; called by muse, mutect2, varscan2
- PTGDR2 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 337/2206 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs1299567960; called by muse, mutect2, varscan2
- PTPN1 | c.923del p.P308Hfs*27 | Frame Shift Del (DEL) | VAF 278/1744 reads (16%) | catalogued as COSV65410014; called by mutect2, pindel, varscan2
- PTPN14 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 243/1705 reads (14%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as rs370626715; called by muse, varscan2
- PTPRQ | c.5297C>T p.A1766V (on ENST00000616559; = p.A1724V on NM_001145026.2) | Missense Mutation (SNP) | VAF 80/649 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs778313896; called by muse, varscan2
- PTPRS | c.4774G>A p.G1592S | Missense Mutation (SNP) | VAF 170/1056 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571743236, COSV53612076; called by muse, mutect2, varscan2
- PTPRT | c.3661C>A p.L1221I | Missense Mutation (SNP) | VAF 189/1332 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61967317; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1621G>T p.V541F | Missense Mutation (SNP) | VAF 151/1126 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV104383893; called by muse, mutect2, varscan2
- RAB44 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 209/1543 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs796830000; called by muse, mutect2, varscan2
- RALGPS1 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 155/1127 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.89); catalogued as rs1051049786, COSV52221362, COSV52225068; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1106A>G p.H369R (on ENST00000408927 / NM_001100427.2; = p.H370R on NM_021159.5) | Missense Mutation (SNP) | VAF 108/890 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as rs375361617; called by muse, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 96/537 reads (18%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM28 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 108/710 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.631); catalogued as rs199999804; called by muse, mutect2, varscan2
- RBSN | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 204/1341 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773059145, COSV53793370; called by muse, mutect2, varscan2
- RECK | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 172/1248 reads (14%) | catalogued as rs376008783; called by muse, mutect2, varscan2
- RERE | c.1433del p.P478Rfs*8 | Frame Shift Del (DEL) | VAF 172/1084 reads (16%) | catalogued as COSV61946838; called by mutect2, pindel, varscan2
- RGS21 | c.405dup p.L136Tfs*4 | Frame Shift Ins (INS) | VAF 92/718 reads (13%) | catalogued as rs746536278; called by mutect2, pindel, varscan2
- RHOBTB2 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 232/1689 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331435808; called by muse, mutect2, varscan2
- RIMBP2 | c.235del p.L79Wfs*15 | Frame Shift Del (DEL) | VAF 267/1791 reads (15%) | catalogued as rs1286661920; called by mutect2, pindel, varscan2
- RIMKLB | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 239/1494 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs181443607; called by muse, mutect2, varscan2
- RIMS1 | c.3935A>G p.Q1312R | Missense Mutation (SNP) | VAF 107/865 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.885); catalogued as rs1008642456; called by muse, mutect2, varscan2
- RIPPLY3 | c.514del p.E172Rfs*50 | Frame Shift Del (DEL) | VAF 216/1360 reads (16%) | catalogued as rs1227193558; called by mutect2, varscan2
- RNF111 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 534/1781 reads (30%) | catalogued as COSV62084267, COSV62087885; called by muse, mutect2, varscan2
- RNF8 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 111/903 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs149686329; called by muse, mutect2, varscan2
- RPL10L | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 213/1417 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs764186971, COSV100022301; called by muse, mutect2, varscan2
- RPL35 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 183/1295 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); catalogued as COSV100780829; called by muse, mutect2, varscan2
- RTCB | c.736dup p.M246Nfs*6 | Frame Shift Ins (INS) | VAF 197/1336 reads (15%) | catalogued as rs771992011; called by mutect2, varscan2
- RUNX1 | c.1139A>G p.Y380C (on ENST00000344691 / NM_001001890.3; = p.Y407C on NM_001754.5) | Missense Mutation (SNP) | VAF 266/1644 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55878223; called by muse, mutect2, varscan2
- SCARF2 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 302/2108 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as rs1281268302; called by muse, mutect2, varscan2
- SENP7 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 96/755 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs766434336, COSV58610954; called by muse, mutect2, varscan2
- SEPTIN4 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 183/1349 reads (14%) | catalogued as rs778224980, COSV57898700; called by muse, mutect2, varscan2
- SERTAD2 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 192/1325 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as rs767846380; called by muse, mutect2, varscan2
- SETD1B | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 241/1590 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.895); catalogued as COSV57349665; called by mutect2, varscan2
- SETD2 | c.7355C>T p.S2452L | Missense Mutation (SNP) | VAF 154/1178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775780402, COSV57434569; called by muse, mutect2, varscan2
- SETDB2 | c.640T>C p.C214R | Missense Mutation (SNP) | VAF 160/1146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1566169400; called by muse, mutect2, varscan2
- SF3A2 | c.995del p.P332Qfs*114 | Frame Shift Del (DEL) | VAF 266/1433 reads (19%) | catalogued as rs771822076; called by mutect2, pindel, varscan2
- SHANK2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 128/877 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs782210973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIRT6 | c.1024del p.H342Tfs*7 | Frame Shift Del (DEL) | VAF 262/1612 reads (16%) | catalogued as rs769236924; called by mutect2, pindel, varscan2
- SLC16A11 | c.122T>C p.V41A (on ENST00000308009; = p.V17A on NM_153357.3) | Missense Mutation (SNP) | VAF 353/2387 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs763026139; called by muse, mutect2, varscan2
- SLC17A7 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 190/1284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55549614, COSV55549814; called by muse, mutect2, varscan2
- SLC22A12 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 226/1496 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs1384341957, COSV60572317; called by muse, varscan2
- SLC25A48 | c.420C>T p.D140= | Splice Region (SNP) | VAF 139/889 reads (16%) | catalogued as rs777873378, COSV99192030; called by muse, mutect2, varscan2
- SLC26A3 | c.353del p.F118Sfs*16 | Frame Shift Del (DEL) | VAF 100/781 reads (13%) | catalogued as rs752963526; called by mutect2, pindel, varscan2
- SLC27A3 | c.1624C>T p.R542W (on ENST00000271857; = p.R414W on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 366/2374 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs182081931; called by muse, mutect2, varscan2
- SLC2A5 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 162/1249 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs371167568; called by muse, mutect2, varscan2
- SLC44A3 | c.1657A>G p.M553V (on ENST00000271227 / NM_001114106.3; = p.M505V on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/942 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs756041627, COSV54731577; called by muse, varscan2
- SLC5A2 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 273/1755 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs149680639, CM087262; called by muse, mutect2, varscan2
- SLC7A2 | c.504del p.F168Lfs*9 (on ENST00000494857 / NM_001370338.1; = p.F208Lfs*9 on NM_003046.6) | Frame Shift Del (DEL) | VAF 137/1107 reads (12%) | catalogued as rs780138939; called by mutect2, pindel, varscan2
- SLC7A9 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 124/882 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs143999252; called by muse, varscan2
- SLC9A2 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 222/1580 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs747383702; called by muse, mutect2, varscan2
- SLCO2A1 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 192/1303 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1275389088, COSV60490091; called by muse, mutect2, varscan2
- SMARCA5 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 104/830 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs759214495, COSV51645986; called by muse, mutect2, varscan2
- SMARCB1 | c.1010C>T p.P337L (on ENST00000263121; = p.P383L on NM_003073.5) | Missense Mutation (SNP) | VAF 369/2433 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as COSV51954125, COSV51955614; called by muse, mutect2, varscan2
- SMARCC2 | c.3043C>A p.Q1015K | Missense Mutation (SNP) | VAF 246/1736 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV53237034; called by mutect2, varscan2
- SMPD4 | c.1613G>A p.R538H (on ENST00000409031 / NM_017951.4; = p.R509H on NM_017751.4) | Missense Mutation (SNP) | VAF 114/1013 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1325049882, COSV99045471; called by muse, mutect2, varscan2
- SNRNP70 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 136/946 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1465556467; called by muse, mutect2, varscan2
- SNX18 | c.1245del p.A416Pfs*42 | Frame Shift Del (DEL) | VAF 263/1730 reads (15%) | catalogued as rs779304883; called by mutect2, pindel, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 100/814 reads (12%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX32 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 227/1445 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs374515235; called by muse, mutect2, varscan2
- SOCS1 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 374/2188 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.455); catalogued as rs749027399; called by muse, mutect2, varscan2
- SORBS1 | c.1072dup p.R358Kfs*5 (on ENST00000361941 / NM_001034954.2; = p.R194Kfs*5 on NM_006434.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 243/1616 reads (15%) | catalogued as rs1210654256; called by mutect2, pindel, varscan2
- SORL1 | c.6479C>T p.T2160M | Missense Mutation (SNP) | VAF 221/1466 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs372203239; called by muse, mutect2, varscan2
- SOX3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 360/2144 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs760010000, COSV65168425; called by muse, mutect2, varscan2
- SPATA16 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 124/950 reads (13%) | catalogued as rs745984261; called by muse, mutect2, varscan2
- SPATA3 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 418/2304 reads (18%) | SIFT deleterious, low confidence (0); catalogued as rs1353305177; called by muse, mutect2, varscan2
- SPATA7 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 73/621 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as rs768713530, COSV99248530; called by muse, mutect2, varscan2
- SPATS2L | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 211/1350 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as rs1194126462, COSV62354372; called by muse, mutect2, varscan2
- SPEG | c.6913G>A p.E2305K | Missense Mutation (SNP) | VAF 316/1968 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.622); catalogued as rs754379643, COSV56665975; called by muse, mutect2, varscan2
- SPNS3 | c.766A>G p.K256E | Missense Mutation (SNP) | VAF 139/880 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV61071633; called by muse, mutect2, varscan2
- SPOCK1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 181/1419 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs768946526; called by muse, mutect2, varscan2
- SPPL2B | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 257/1789 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.093); catalogued as rs529477585; called by muse, mutect2, varscan2
- SPRY4 | c.697G>A p.A233T (on ENST00000434127 / NM_001127496.3; = p.A256T on NM_030964.4) | Missense Mutation (SNP) | VAF 294/1758 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.745); catalogued as rs761651255, COSV100702209, COSV100702211; called by muse, mutect2, varscan2
- SRF | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 200/1254 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs763406737; called by muse, varscan2
- SSH1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 206/1354 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1222844460, COSV58457131; called by muse, mutect2, varscan2
- SSH1 | c.714del p.A239Rfs*25 | Frame Shift Del (DEL) | VAF 139/963 reads (14%) | catalogued as COSV58460169; called by mutect2, pindel, varscan2
- STK32C | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 215/1311 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs754644339, COSV53838008; called by muse, mutect2, varscan2
- STOX2 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 222/1273 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772535660, COSV100408744; called by muse, mutect2, varscan2
- STXBP4 | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 138/1124 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs143730464; called by muse, mutect2, varscan2
- SULF2 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 146/1113 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1273104352, COSV63417734; called by muse, mutect2, varscan2
- SYCE2 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 192/1199 reads (16%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.058); catalogued as COSV53366806; called by muse, mutect2, varscan2
- SYCP2 | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 116/774 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs1195019660, COSV62765650; called by muse, varscan2
- SYNE2 | c.3664C>T p.R1222W | Missense Mutation (SNP) | VAF 142/917 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs773994020, COSV100648495; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAS1R2 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 257/1519 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.535); catalogued as rs376688216; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 117/916 reads (13%) | catalogued as rs763321097; called by mutect2, varscan2
- TEKT1 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 107/936 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs199498472, COSV58624074; called by muse, mutect2, varscan2
- TGM6 | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 169/1043 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.389); catalogued as rs769042038, COSV99171718; called by muse, mutect2, varscan2
- THSD7B | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 110/829 reads (13%) | catalogued as rs777485945, COSV55658875; called by muse, mutect2, varscan2
- TICRR | c.1104G>T p.E368D | Missense Mutation (SNP) | VAF 174/1230 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1319886262, COSV51537912; called by muse, mutect2, varscan2
- TJP1 | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 116/828 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as rs768807966; called by muse, mutect2, varscan2
- TMCC2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 341/2051 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201022917; called by muse, mutect2, varscan2
- TMEM121 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 416/2444 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as rs1189287802, COSV66796086; called by muse, mutect2, varscan2
- TMEM63C | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 158/1213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759011366, COSV53600834; called by muse, mutect2, varscan2
- TNKS2 | c.2102A>G p.H701R | Missense Mutation (SNP) | VAF 102/844 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs757239643; called by muse, mutect2, varscan2
- TNN | c.3674C>T p.A1225V | Missense Mutation (SNP) | VAF 175/1369 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV53424023; called by muse, mutect2, varscan2
- TNPO2 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 268/1738 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV63507627; called by muse, mutect2, varscan2
- TOMM20L | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 144/1002 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1459257704; called by muse, mutect2, varscan2
- TP53I13 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 187/1309 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs577200698; called by muse, mutect2, varscan2
- TPO | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 354/2279 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369225819; called by muse, mutect2, varscan2
- TRAF5 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 176/1328 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs748492186, COSV54822757; called by muse, mutect2, varscan2
- TRAPPC12 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 117/929 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1209116401, COSV60849843, COSV60851063; called by muse, mutect2, varscan2
- TRAPPC9 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 192/1406 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66901683; called by muse, mutect2, varscan2
- TRIM32 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 223/1497 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs765158423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM50 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 263/1631 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.341); catalogued as rs370443781; called by muse, mutect2, varscan2
- TRIM9 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 191/1156 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1431463984, COSV53612929; called by muse, mutect2, varscan2
- TRIO | c.8834C>T p.T2945M | Missense Mutation (SNP) | VAF 210/1421 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs574639687; called by muse, mutect2, varscan2
- TRMT12 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 242/1774 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100149202; called by muse, mutect2, varscan2
- TTN | c.100564C>A p.L33522M (on ENST00000591111; = p.L26098M on NM_003319.4) | Missense Mutation (SNP) | VAF 185/1303 reads (14%) | PolyPhen benign (0.009); catalogued as COSV100634623; called by muse, mutect2, varscan2
- UBN2 | c.941del p.K314Rfs*11 | Frame Shift Del (DEL) | VAF 82/639 reads (13%) | catalogued as rs1427812488, COSV99943446; called by mutect2, pindel, varscan2
- UGT1A8 | c.364del p.S122Rfs*12 | Frame Shift Del (DEL) | VAF 85/814 reads (10%) | catalogued as rs762306873; called by pindel, varscan2
- VPS13A | c.4936G>A p.V1646I | Missense Mutation (SNP) | VAF 87/580 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs770575409; called by muse, mutect2, varscan2
- VPS13B | c.5608dup p.T1870Nfs*12 | Frame Shift Ins (INS) | VAF 126/1098 reads (11%) | catalogued as rs1176397159; called by mutect2, pindel, varscan2
- VPS37D | c.748del p.H250Tfs*75 | Frame Shift Del (DEL) | VAF 67/432 reads (16%) | catalogued as rs1563540888; called by mutect2, pindel, varscan2
- WDFY2 | c.336G>A p.A112= | Splice Region (SNP) | VAF 133/799 reads (17%) | catalogued as rs1383576987, COSV53289278; called by muse, mutect2, varscan2
- WDFY3 | c.8309G>A p.R2770Q | Missense Mutation (SNP) | VAF 117/820 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560564400; called by muse, mutect2, varscan2
- WDFY4 | c.5527C>T p.R1843W | Missense Mutation (SNP) | VAF 155/1167 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs747717433, COSV55441096; called by muse, mutect2, varscan2
- WDR90 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 177/1107 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745634832, COSV53472386; called by muse, mutect2, varscan2
- WDR93 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 117/752 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs376704792, COSV99175872; called by muse, mutect2, varscan2
- WT1 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 305/2275 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs1554946595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WWP2 | c.2048C>T p.T683M | Missense Mutation (SNP) | VAF 212/1540 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs371214769; called by muse, mutect2, varscan2
- XAB2 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 339/1864 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372229800; called by muse, mutect2, varscan2
- YBX2 | c.239del p.P80Rfs*81 | Frame Shift Del (DEL) | VAF 297/1524 reads (19%) | catalogued as rs1567605546, CM094250; called by mutect2, pindel, varscan2
- ZACN | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 213/1295 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV104401422; called by muse, mutect2, varscan2
- ZC3H18 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 342/2162 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1350106436; called by muse, mutect2, varscan2
- ZDHHC5 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 150/1064 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1328910163, COSV54705570; called by muse, mutect2, varscan2
- ZFHX4 | c.1230del p.L411Cfs*4 | Frame Shift Del (DEL) | VAF 174/1310 reads (13%) | catalogued as COSV99265992; called by mutect2, varscan2
- ZHX2 | c.427T>A p.L143I | Missense Mutation (SNP) | VAF 191/1455 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.867); catalogued as COSV58716875; called by muse, mutect2, varscan2
- ZNF23 | c.1391T>C p.M464T | Missense Mutation (SNP) | VAF 91/1810 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0.131); catalogued as rs142923016; called by muse, mutect2
- ZNF385B | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 250/1731 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308267667, COSV69803498; called by muse, mutect2, varscan2
- ZNF561 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 111/829 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.228); catalogued as rs754290323, COSV100254523; called by muse, mutect2, varscan2
- ZNF57 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 231/1348 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs150372606; called by muse, mutect2, varscan2
- ZNF596 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 160/1323 reads (12%) | catalogued as rs145428583; called by muse, mutect2, varscan2
- ZNF7 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 217/1714 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs745767675, COSV57383197; called by muse, mutect2, varscan2
- ZNF710 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 198/1448 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs372301042; called by muse, mutect2, varscan2
- ZNF878 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 127/1048 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV104438550; called by mutect2, varscan2
- ZNFX1 | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 240/1495 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230577367; called by muse, mutect2, varscan2
- ZSCAN1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 353/2181 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.466); catalogued as rs546837948, COSV56603607; called by muse, mutect2, varscan2
- ZSCAN25 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 228/1498 reads (15%) | catalogued as rs1562971601, COSV53553470; called by muse, mutect2, varscan2
- AASDH | c.1436A>G p.Q479R | Missense Mutation (SNP) | VAF 98/893 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AC006059.2 | c.1291A>C p.T431P | Missense Mutation (SNP) | VAF 187/1296 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ACKR3 | c.1082C>A p.T361N | Missense Mutation (SNP) | VAF 105/669 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACTB | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 171/1118 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACTL10 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 305/1951 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ACTL9 | c.1076_1078del p.L359del | In Frame Del (DEL) | VAF 235/1680 reads (14%) | called by pindel, varscan2
- ACVR2A | c.1309_1310del p.K437Efs*19 | Frame Shift Del (DEL) | VAF 183/1394 reads (13%) | called by pindel, varscan2*
- ADA2 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 138/1006 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM18 | c.1698A>C p.Q566H | Missense Mutation (SNP) | VAF 159/1518 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADGRG4 | c.4720C>A p.P1574T | Missense Mutation (SNP) | VAF 180/1246 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADRA2C | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 141/1067 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK | c.6094A>G p.I2032V | Missense Mutation (SNP) | VAF 146/928 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AKAP9 | c.3854C>T p.T1285I | Missense Mutation (SNP) | VAF 107/807 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP9 | c.6289del p.M2097* (on ENST00000359028; = p.M2065* on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 79/679 reads (12%) | called by mutect2, pindel, varscan2
- AKR1B10 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 142/1085 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- AL645922.1 | c.1814G>A p.C605Y | Missense Mutation (SNP) | VAF 191/1411 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AL772284.1 | c.212del p.G71Vfs*12 | Frame Shift Del (DEL) | VAF 176/1534 reads (11%) | called by pindel, varscan2
- ALDH18A1 | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 151/1163 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMBP | c.162dup p.W55Lfs*38 | Frame Shift Ins (INS) | VAF 204/1398 reads (15%) | called by mutect2, pindel, varscan2
- AMBRA1 | c.1405G>T p.G469W (on ENST00000458649 / NM_001367468.1; = p.G379W on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 236/1419 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK2 | c.4212del p.F1404Lfs*28 | Frame Shift Del (DEL) | VAF 122/960 reads (13%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.4215del p.K1405Nfs*10 | Frame Shift Del (DEL) | VAF 114/858 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD30BL | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 123/880 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- APOL6 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 297/1587 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ARHGAP11A | c.1576A>G p.N526D | Missense Mutation (SNP) | VAF 216/1361 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP15 | c.1097T>A p.L366H | Missense Mutation (SNP) | VAF 147/1060 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP45 | c.481A>G p.M161V | Missense Mutation (SNP) | VAF 205/1373 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ARX | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 217/1627 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ASCL5 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 210/1478 reads (14%) | SIFT tolerated (0.15); called by mutect2, varscan2
- ATAD2B | c.1392del p.V465Wfs*12 | Frame Shift Del (DEL) | VAF 210/1419 reads (15%) | called by mutect2, pindel, varscan2
- ATG2A | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 296/2190 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- AVPR1B | c.418del p.L140Cfs*38 | Frame Shift Del (DEL) | VAF 279/1988 reads (14%) | called by mutect2, pindel, varscan2
- AXIN1 | c.976C>A p.L326M | Missense Mutation (SNP) | VAF 108/1866 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by muse, mutect2
- B3GNT5 | c.36del p.K12Nfs*4 | Frame Shift Del (DEL) | VAF 103/796 reads (13%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 389/2417 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- BCL9L | c.308del p.P103Lfs*9 | Frame Shift Del (DEL) | VAF 238/1718 reads (14%) | called by mutect2, pindel, varscan2
- BCORL1 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 364/1974 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- BCR | c.252del p.D85Tfs*94 | Frame Shift Del (DEL) | VAF 255/1765 reads (14%) | called by mutect2, pindel, varscan2
- BDH1 | c.512dup p.T172Hfs*54 | Frame Shift Ins (INS) | VAF 245/1796 reads (14%) | called by mutect2, pindel, varscan2
- BMP8B | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 276/1892 reads (15%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- BNC2 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 135/898 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- BOD1L1 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 117/1087 reads (11%) | called by mutect2, varscan2
- BRCA2 | c.5764G>A p.A1922T | Missense Mutation (SNP) | VAF 148/1061 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- BRMS1 | c.321del p.L108Cfs*22 | Frame Shift Del (DEL) | VAF 172/1062 reads (16%) | called by mutect2, varscan2
- BTBD3 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 122/934 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- BTN3A2 | c.878T>C p.M293T | Missense Mutation (SNP) | VAF 93/626 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C1QTNF12 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 301/1816 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- C2orf92 | c.765del p.K255Nfs*5 | Frame Shift Del (DEL) | VAF 161/1329 reads (12%) | called by mutect2, pindel, varscan2
- C6orf132 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 106/1242 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- C8G | c.96del p.I33Sfs*116 | Frame Shift Del (DEL) | VAF 192/1816 reads (11%) | called by pindel, varscan2
- CACNA1B | c.5273C>T p.P1758L | Missense Mutation (SNP) | VAF 147/1263 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1I | c.3267del p.H1091Mfs*43 | Frame Shift Del (DEL) | VAF 268/1927 reads (14%) | called by mutect2, pindel, varscan2
- CAMK2A | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 161/1254 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMTA1 | c.4904del p.K1635Sfs*9 | Frame Shift Del (DEL) | VAF 149/1123 reads (13%) | called by mutect2, pindel, varscan2
- CBX3 | c.31del p.M11Wfs*26 | Frame Shift Del (DEL) | VAF 126/926 reads (14%) | called by mutect2, pindel, varscan2
- CDC42BPG | c.2435T>C p.L812P | Missense Mutation (SNP) | VAF 147/1040 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDC42EP5 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 281/1855 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- CDH2 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 119/855 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKL4 | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 144/973 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDV3 | c.273del p.E92Rfs*14 | Frame Shift Del (DEL) | VAF 147/968 reads (15%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.876dup p.Y293Lfs*46 | Frame Shift Ins (INS) | VAF 175/1368 reads (13%) | called by mutect2, pindel, varscan2
- CEND1 | c.134del p.P45Rfs*34 | Frame Shift Del (DEL) | VAF 357/2269 reads (16%) | called by mutect2, pindel, varscan2
- CENPE | c.5986del p.I1996Lfs*7 | Frame Shift Del (DEL) | VAF 118/874 reads (14%) | called by pindel, varscan2
- CEP250 | c.4813C>T p.Q1605* | Nonsense Mutation (SNP) | VAF 155/1180 reads (13%) | called by muse, mutect2, varscan2
- CEP350 | c.5174del p.K1725Nfs*24 | Frame Shift Del (DEL) | VAF 91/677 reads (13%) | called by mutect2, pindel, varscan2
- CERT1 | c.661A>G p.S221G (on ENST00000405807 / NM_001130105.1; = p.S93G on NM_005713.3) | Missense Mutation (SNP) | VAF 134/961 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CFAP20DC | c.727A>G p.N243D (on ENST00000482387 / NM_001351530.2; = p.N118D on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/800 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CFAP52 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 122/847 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CHD3 | c.1940A>G p.Y647C | Missense Mutation (SNP) | VAF 90/701 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHRM5 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 203/1454 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CHST14 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 322/1978 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- CHST9 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 90/934 reads (10%) | called by muse, mutect2
- CLCN1 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 146/895 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CLEC4E | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 118/935 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CLEC9A | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 163/1105 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CNTN4 | c.1477G>T p.V493L | Missense Mutation (SNP) | VAF 96/603 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COBL | c.3267del p.F1089Lfs*25 | Frame Shift Del (DEL) | VAF 236/1561 reads (15%) | called by mutect2, pindel, varscan2
- COL11A2 | c.3803C>A p.P1268H (on ENST00000341947 / NM_080680.3; = p.P1161H on NM_080679.2) | Missense Mutation (SNP) | VAF 197/1460 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL4A1 | c.1763dup p.G589Wfs*11 | Frame Shift Ins (INS) | VAF 143/1231 reads (12%) | called by mutect2, pindel, varscan2
- COPRS | c.37del p.A13Pfs*43 | Frame Shift Del (DEL) | VAF 259/1608 reads (16%) | called by mutect2, varscan2
- CPEB1 | c.123del p.F41Lfs*10 | Frame Shift Del (DEL) | VAF 173/1180 reads (15%) | called by mutect2, pindel, varscan2
- CPVL | c.1251del p.V418Ffs*24 | Frame Shift Del (DEL) | VAF 224/1326 reads (17%) | called by mutect2, varscan2
- CROCC2 | c.1150del p.H384Ifs*26 | Frame Shift Del (DEL) | VAF 304/2104 reads (14%) | called by mutect2, pindel, varscan2
- CRTC1 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 210/1360 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, varscan2
- CSF3R | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 224/1483 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSTF1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 251/1582 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CTDSPL2 | c.1367G>T p.R456I | Missense Mutation (SNP) | VAF 243/961 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CTTNBP2NL | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 266/1616 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CUBN | c.9252T>A p.D3084E | Missense Mutation (SNP) | VAF 143/884 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP4F3 | c.206G>C p.S69T | Missense Mutation (SNP) | VAF 140/924 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DDX28 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 273/1759 reads (16%) | called by muse, mutect2, varscan2
- DDX56 | c.1362_1364del p.L455del | In Frame Del (DEL) | VAF 159/1189 reads (13%) | called by mutect2, pindel, varscan2
- DHX8 | c.2966T>C p.L989P | Missense Mutation (SNP) | VAF 123/917 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMRTB1 | c.890del p.P297Rfs*13 | Frame Shift Del (DEL) | VAF 272/1816 reads (15%) | called by mutect2, varscan2
- DMTN | c.364del p.R122Gfs*109 | Frame Shift Del (DEL) | VAF 264/1934 reads (14%) | called by mutect2, varscan2
- DNAH8 | c.9786dup p.V3263Sfs*23 | Frame Shift Ins (INS) | VAF 169/1187 reads (14%) | called by mutect2, pindel, varscan2
- DNAJC11 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 170/1076 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by mutect2, varscan2
- DNAJC13 | c.3983C>T p.A1328V | Missense Mutation (SNP) | VAF 119/1039 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DOCK4 | c.779T>C p.F260S | Missense Mutation (SNP) | VAF 117/844 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DTX2 | c.1196del p.N399Tfs*6 | Frame Shift Del (DEL) | VAF 50/178 reads (28%) | called by mutect2, varscan2
- ECPAS | c.5214del p.Q1739Rfs*3 | Frame Shift Del (DEL) | VAF 113/808 reads (14%) | called by mutect2, pindel, varscan2
- EDN3 | c.289T>G p.C97G | Missense Mutation (SNP) | VAF 88/1848 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELL2 | c.184G>T p.G62* | Nonsense Mutation (SNP) | VAF 73/612 reads (12%) | called by muse, mutect2, varscan2
- ENAM | c.1048del p.Y350Tfs*22 | Frame Shift Del (DEL) | VAF 169/1085 reads (16%) | called by mutect2, pindel, varscan2
- EP400 | c.3830A>G p.E1277G | Missense Mutation (SNP) | VAF 180/1257 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 220/1306 reads (17%) | called by mutect2, varscan2
- EPN1 | c.1259G>A p.S420N (on ENST00000270460 / NM_001321263.1; = p.S394N on NM_013333.3) | Missense Mutation (SNP) | VAF 143/1044 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- EPRS1 | c.2231G>A p.C744Y | Missense Mutation (SNP) | VAF 107/726 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ERBB4 | c.1869A>G p.Q623= | Splice Region (SNP) | VAF 131/836 reads (16%) | called by muse, mutect2, varscan2
- ERVMER34-1 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 160/1077 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, varscan2
- ESRP2 | c.75dup p.W26Lfs*36 | Frame Shift Ins (INS) | VAF 319/2184 reads (15%) | called by mutect2, pindel, varscan2
- EWSR1 | c.1385A>C p.E462A | Missense Mutation (SNP) | VAF 218/1492 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EXOC3L1 | c.1431dup p.K478Efs*81 | Frame Shift Ins (INS) | VAF 188/1325 reads (14%) | called by mutect2, pindel, varscan2
- EXOC3L2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 355/2015 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- FAAP100 | c.2051G>T p.R684L | Missense Mutation (SNP) | VAF 324/2063 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM207A | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 179/1226 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM76B | c.147A>C p.Q49H | Missense Mutation (SNP) | VAF 82/668 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FAM9A | c.476_477del p.K159Tfs*8 | Frame Shift Del (DEL) | VAF 106/781 reads (14%) | called by mutect2, varscan2
- FASN | c.6060_6062del p.S2021del | In Frame Del (DEL) | VAF 194/1453 reads (13%) | called by pindel, varscan2
- FAT2 | c.12709G>A p.A4237T | Missense Mutation (SNP) | VAF 254/1643 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FBLN5 | c.874T>C p.C292R | Missense Mutation (SNP) | VAF 59/1186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- FBXO10 | c.689del p.N230Tfs*27 | Frame Shift Del (DEL) | VAF 240/1424 reads (17%) | called by mutect2, pindel, varscan2
- FCRL4 | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 142/984 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- FEM1C | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 121/867 reads (14%) | called by muse, mutect2, varscan2
- FGB | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 131/1001 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- FREM3 | c.4411G>T p.G1471C | Missense Mutation (SNP) | VAF 209/1314 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRG2C | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 171/3568 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); called by muse, mutect2
- FRMPD1 | c.4324del p.V1442Lfs*35 | Frame Shift Del (DEL) | VAF 248/1675 reads (15%) | called by mutect2, pindel, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 273/1864 reads (15%) | called by mutect2, pindel, varscan2
- GAD1 | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 191/1399 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAS2L2 | c.1008del p.T337Pfs*25 | Frame Shift Del (DEL) | VAF 194/1368 reads (14%) | called by mutect2, pindel, varscan2
- GCC2 | c.2106del p.K702Nfs*3 | Frame Shift Del (DEL) | VAF 154/804 reads (19%) | called by mutect2, varscan2
- GEMIN5 | c.1452del p.M485Cfs*58 | Frame Shift Del (DEL) | VAF 81/768 reads (11%) | called by mutect2, pindel, varscan2
- GFRA4 | c.562C>T p.R188C (on ENST00000319242 / NM_145762.3; = p.R161= on NM_022139.4) | Missense Mutation (SNP) | VAF 304/1822 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GGTLC1 | c.530A>G p.Q177R | Missense Mutation (SNP) | VAF 154/1019 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GK3P | c.1103A>G p.Y368C | Missense Mutation (SNP) | VAF 184/1373 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GLI2 | c.2495C>T p.A832V (on ENST00000361492 / NM_001374353.1; = p.A849V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 395/2452 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GOLGA6L7 | c.1652C>A p.P551H | Missense Mutation (SNP) | VAF 146/973 reads (15%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- GPR4 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 237/1484 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- GRIK5 | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 346/2295 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GRM8 | c.644G>C p.W215S | Missense Mutation (SNP) | VAF 170/1406 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSDMA | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 94/1170 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2
- GTPBP8 | c.616del p.T206Qfs*6 | Frame Shift Del (DEL) | VAF 130/951 reads (14%) | called by mutect2, pindel, varscan2
- GUCY1A2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 335/2308 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- HACD3 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 97/787 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HAUS2 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 129/645 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- HCFC1 | c.5293dup p.Q1765Pfs*50 | Frame Shift Ins (INS) | VAF 232/1742 reads (13%) | called by mutect2, pindel, varscan2
- HDAC2 | c.1375dup p.T459Nfs*4 | Frame Shift Ins (INS) | VAF 75/493 reads (15%) | called by mutect2, varscan2
- HECTD4 | c.3256C>A p.P1086T | Missense Mutation (SNP) | VAF 144/1106 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- HECW2 | c.2210G>A p.W737* | Nonsense Mutation (SNP) | VAF 281/1919 reads (15%) | called by muse, mutect2, varscan2
- HERC2 | c.3588del p.F1196Lfs*12 | Frame Shift Del (DEL) | VAF 85/594 reads (14%) | called by mutect2, pindel, varscan2
- HGSNAT | c.1670T>C p.L557P | Missense Mutation (SNP) | VAF 170/1287 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- HLA-B | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 180/1643 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNF4A | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 162/1265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HNRNPUL2 | c.2190_2191insA p.Q731Tfs*54 | Frame Shift Ins (INS) | VAF 111/935 reads (12%) | called by mutect2, pindel, varscan2
- HOOK2 | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 147/1245 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSPA12B | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 349/2186 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- HSPA1A | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 165/1473 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ICAM3 | c.1621del p.E541Kfs*? | Frame Shift Del (DEL) | VAF 166/1045 reads (16%) | called by mutect2, pindel, varscan2
- ICAM4 | c.361del p.T121Hfs*17 | Frame Shift Del (DEL) | VAF 260/1666 reads (16%) | called by mutect2, pindel, varscan2
- ICMT | c.803_805del p.K268del | In Frame Del (DEL) | VAF 136/980 reads (14%) | called by pindel, varscan2
- IDH2 | c.586T>G p.F196V | Missense Mutation (SNP) | VAF 228/1578 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- IFNL3 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 236/1587 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGFBP4 | c.665A>G p.Q222R | Missense Mutation (SNP) | VAF 220/1420 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, varscan2
- IGHV3-23 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 125/1680 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.076); called by muse, mutect2
- IL12A | c.128T>A p.L43H | Missense Mutation (SNP) | VAF 158/929 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1538G>A p.S513N | Missense Mutation (SNP) | VAF 184/1443 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- IL1RL1 | c.1054del p.M352Cfs*13 | Frame Shift Del (DEL) | VAF 126/924 reads (14%) | called by mutect2, pindel, varscan2
- INAVA | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 284/1849 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- INSC | c.88T>C p.C30R | Missense Mutation (SNP) | VAF 210/1217 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQGAP2 | c.1871C>T p.T624I | Missense Mutation (SNP) | VAF 93/1097 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- IRF9 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 212/1612 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, varscan2
- IRX5 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 246/1669 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ITGAM | c.3350del p.G1117Dfs*25 (on ENST00000648685 / NM_001145808.2; = p.G1116Dfs*25 on NM_000632.4) | Frame Shift Del (DEL) | VAF 212/1474 reads (14%) | called by mutect2, pindel, varscan2
- ITIH1 | c.686del p.K229Rfs*10 | Frame Shift Del (DEL) | VAF 136/1003 reads (14%) | called by mutect2, pindel, varscan2
- IVL | c.1502dup p.H502Afs*84 | Frame Shift Ins (INS) | VAF 265/1813 reads (15%) | called by mutect2, pindel, varscan2
- KANSL1L | c.932del p.N311Mfs*63 | Frame Shift Del (DEL) | VAF 157/1352 reads (12%) | called by mutect2, pindel, varscan2
- KAT8 | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 227/1523 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KATNIP | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 144/1089 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- KBTBD11 | c.484A>G p.S162G | Missense Mutation (SNP) | VAF 290/2462 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNC3 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 39/490 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); called by muse, mutect2
- KCNT2 | c.2326T>C p.Y776H | Missense Mutation (SNP) | VAF 118/938 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- KDM6B | c.1960del p.Q654Sfs*46 | Frame Shift Del (DEL) | VAF 237/1773 reads (13%) | called by mutect2, pindel, varscan2
- KIAA1586 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 143/1007 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF1C | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 343/2228 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF26B | c.3593T>G p.I1198S | Missense Mutation (SNP) | VAF 317/2194 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- KIFC2 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 438/2954 reads (15%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 94/1013 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2
- KL | c.2771G>T p.R924M | Missense Mutation (SNP) | VAF 186/1191 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, varscan2
- KLHL29 | c.2216A>G p.N739S | Missense Mutation (SNP) | VAF 228/1588 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- KMT2B | c.6641del p.P2214Qfs*2 | Frame Shift Del (DEL) | VAF 259/1090 reads (24%) | called by mutect2, pindel, varscan2
- KMT2D | c.14051del p.P4684Lfs*113 | Frame Shift Del (DEL) | VAF 214/1409 reads (15%) | called by mutect2, pindel, varscan2
- KNL1 | c.5944del p.M1982* (on ENST00000346991 / NM_170589.5; = p.M1956* on NM_144508.5) | Frame Shift Del (DEL) | VAF 109/687 reads (16%) | called by mutect2, pindel, varscan2
- LACC1 | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 121/910 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LHX9 | c.53del p.P18Qfs*76 | Frame Shift Del (DEL) | VAF 202/1471 reads (14%) | called by mutect2, pindel, varscan2
- LMTK3 | c.4283del p.P1428Rfs*56 | Frame Shift Del (DEL) | VAF 167/1122 reads (15%) | called by mutect2, pindel, varscan2
- LRCH3 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 103/671 reads (15%) | called by muse, mutect2, varscan2
- LRP1 | c.5212T>G p.F1738V | Missense Mutation (SNP) | VAF 220/1434 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LRP1 | c.13193A>G p.Q4398R | Missense Mutation (SNP) | VAF 146/971 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRP10 | c.1558T>G p.S520A | Missense Mutation (SNP) | VAF 142/867 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- LTBP1 | c.3586G>A p.D1196N (on ENST00000404816 / NM_206943.4; = p.D870N on NM_000627.4) | Missense Mutation (SNP) | VAF 106/694 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MALRD1 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 71/617 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAML2 | c.1867T>C p.S623P | Missense Mutation (SNP) | VAF 332/1872 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.097); called by muse, varscan2
- MAN2A2 | c.420T>G p.F140L | Missense Mutation (SNP) | VAF 243/1432 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAN2B2 | c.1890del p.I631Ffs*30 | Frame Shift Del (DEL) | VAF 241/1585 reads (15%) | called by mutect2, pindel, varscan2
- MAPK8 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 164/1160 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBOAT1 | c.548del p.L183Wfs*4 | Frame Shift Del (DEL) | VAF 95/734 reads (13%) | called by mutect2, pindel, varscan2
- MEF2C | c.73A>G p.K25E | Missense Mutation (SNP) | VAF 130/1002 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MEIS2 | c.825del p.K275Nfs*12 (on ENST00000561208 / NM_170675.5; = p.K262Nfs*12 on NM_002399.3) | Frame Shift Del (DEL) | VAF 226/1500 reads (15%) | called by mutect2, pindel, varscan2
- METTL21C | c.467del p.N156Tfs*12 | Frame Shift Del (DEL) | VAF 152/1239 reads (12%) | called by mutect2, pindel, varscan2
- MFSD13A | c.73T>G p.F25V | Missense Mutation (SNP) | VAF 223/1521 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MFSD6 | c.1489T>C p.Y497H | Missense Mutation (SNP) | VAF 126/912 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MGA | c.2453dup p.N818Kfs*7 | Frame Shift Ins (INS) | VAF 128/925 reads (14%) | called by mutect2, pindel, varscan2
- MIDN | c.608dup p.V204Gfs*99 | Frame Shift Ins (INS) | VAF 361/2604 reads (14%) | called by mutect2, pindel, varscan2
- MINAR2 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 145/1087 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MKNK2 | c.542A>G p.E181G | Missense Mutation (SNP) | VAF 250/1769 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MMD | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 93/926 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- MMP14 | c.854dup p.X285_splice | Splice Site (INS) | VAF 140/831 reads (17%) | called by mutect2, pindel, varscan2
- MMP26 | c.331T>C p.Y111H | Missense Mutation (SNP) | VAF 86/659 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- MMP26 | c.527T>C p.L176S | Missense Mutation (SNP) | VAF 116/909 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MRPS35 | c.278del p.K93Rfs*11 | Frame Shift Del (DEL) | VAF 165/1162 reads (14%) | called by mutect2, pindel, varscan2
- MSH6 | c.2831T>C p.I944T | Missense Mutation (SNP) | VAF 223/1386 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MTFR2 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 124/759 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MYEF2 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 695/2210 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- MYH14 | c.4508T>C p.L1503P | Missense Mutation (SNP) | VAF 291/1809 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO3B | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 167/1163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO5B | c.3496C>T p.Q1166* | Nonsense Mutation (SNP) | VAF 139/1064 reads (13%) | called by muse, mutect2, varscan2
- NABP2 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 161/1157 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NAGPA | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 380/2307 reads (16%) | PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- NCR1 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 165/1206 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- NECTIN3 | c.1158del p.K386Nfs*24 | Frame Shift Del (DEL) | VAF 209/1214 reads (17%) | called by mutect2, varscan2
- NEIL3 | c.1731del p.F577Lfs*23 | Frame Shift Del (DEL) | VAF 181/1245 reads (15%) | called by mutect2, pindel, varscan2
- NEMP2 | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 199/1216 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NFATC2 | c.1967T>C p.V656A | Missense Mutation (SNP) | VAF 150/1137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFX1 | c.1604G>C p.S535T | Missense Mutation (SNP) | VAF 122/829 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NFXL1 | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 131/864 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NGFR | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 167/1123 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NIN | c.1304del p.N435Mfs*19 | Frame Shift Del (DEL) | VAF 195/1236 reads (16%) | called by mutect2, pindel, varscan2
- NKX2-5 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 319/1940 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOMO1 | c.2171del p.N724Tfs*10 | Frame Shift Del (DEL) | VAF 251/1967 reads (13%) | called by mutect2, pindel, varscan2
- NRAP | c.497dup p.K167Qfs*28 | Frame Shift Ins (INS) | VAF 165/1073 reads (15%) | called by mutect2, pindel, varscan2
- NSD3 | c.963G>T p.W321C | Missense Mutation (SNP) | VAF 176/1458 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP205 | c.4484T>C p.L1495P | Missense Mutation (SNP) | VAF 95/733 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ODF2 | c.317G>A p.S106N (on ENST00000434106 / NM_153433.2; = p.S82N on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 161/1354 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- ODF3L1 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 196/1416 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- OLR1 | c.253A>C p.I85L | Missense Mutation (SNP) | VAF 175/1312 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10T2 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 158/1089 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2C3 | c.580A>C p.S194R | Missense Mutation (SNP) | VAF 223/1379 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2S2 | c.356T>C p.M119T | Missense Mutation (SNP) | VAF 225/1373 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- OR2T11 | c.524dup p.C176Lfs*2 | Frame Shift Ins (INS) | VAF 159/1135 reads (14%) | called by mutect2, pindel, varscan2
- OR4A5 | c.388T>C p.Y130H | Missense Mutation (SNP) | VAF 146/942 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- OR4F6 | c.635del p.L212* | Frame Shift Del (DEL) | VAF 125/1004 reads (12%) | called by mutect2, pindel, varscan2
- OR5T1 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 134/1107 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- OSBP2 | c.1880_1881del p.H627Pfs*81 | Frame Shift Del (DEL) | VAF 130/916 reads (14%) | called by mutect2, pindel, varscan2
- PANX2 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 375/2396 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PAOX | c.1414del p.E472Kfs*54 | Frame Shift Del (DEL) | VAF 218/1335 reads (16%) | called by mutect2, pindel, varscan2
- PARP8 | c.2319del p.G774Dfs*12 | Frame Shift Del (DEL) | VAF 113/784 reads (14%) | called by pindel, varscan2
- PBXIP1 | c.1811G>A p.G604D | Missense Mutation (SNP) | VAF 222/1552 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDH17 | c.317T>A p.L106H | Missense Mutation (SNP) | VAF 241/1737 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDH7 | c.2798del p.K933Sfs*194 | Frame Shift Del (DEL) | VAF 232/1595 reads (15%) | called by mutect2, pindel, varscan2
- PCDH8 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 165/1002 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PCDHA11 | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 213/1584 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- PCDHA5 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 98/888 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- PCDHB13 | c.2311A>G p.I771V | Missense Mutation (SNP) | VAF 130/1128 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.13096C>A p.P4366T | Missense Mutation (SNP) | VAF 159/1032 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.3657del p.K1219Nfs*2 | Frame Shift Del (DEL) | VAF 140/880 reads (16%) | called by mutect2, varscan2
- PDIA2 | c.24_26del p.L14del | In Frame Del (DEL) | VAF 163/1088 reads (15%) | called by mutect2, pindel, varscan2
- PDK3 | c.182T>C p.M61T | Missense Mutation (SNP) | VAF 179/1394 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- PHLPP1 | c.4964C>G p.P1655R | Missense Mutation (SNP) | VAF 197/1305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PI4KB | c.860G>A p.S287N (on ENST00000368873 / NM_001369623.1; = p.S299N on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/984 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIEZO2 | c.4597_4598del p.K1533Afs*8 | Frame Shift Del (DEL) | VAF 202/1397 reads (14%) | called by pindel, varscan2*
- PLA2R1 | c.3514C>T p.H1172Y | Missense Mutation (SNP) | VAF 121/879 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PLCD4 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 239/1453 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, varscan2
- PLEC | c.4547A>G p.H1516R (on ENST00000322810 / NM_201380.4; = p.H1406R on NM_000445.5) | Missense Mutation (SNP) | VAF 335/2574 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PLEKHM1 | c.65T>A p.L22Q | Missense Mutation (SNP) | VAF 144/923 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA4 | c.1979A>G p.N660S | Missense Mutation (SNP) | VAF 77/665 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PNMT | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 155/1080 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPAT | c.1431dup p.Q478Tfs*21 | Frame Shift Ins (INS) | VAF 119/873 reads (14%) | called by mutect2, pindel, varscan2
- PPM1N | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 326/2188 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, varscan2
- PRDM13 | c.209T>C p.L70S | Missense Mutation (SNP) | VAF 166/1306 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PRDM2 | c.2452G>A p.V818M | Missense Mutation (SNP) | VAF 206/1249 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRG4 | c.2558C>G p.T853S | Missense Mutation (SNP) | VAF 210/1455 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PRH1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 80/1036 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PRKCE | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 157/1082 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKD1 | c.2645C>T p.T882I | Missense Mutation (SNP) | VAF 193/1265 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRNP | c.174del p.Q59Sfs*51 | Frame Shift Del (DEL) | VAF 308/2349 reads (13%) | called by mutect2, pindel, varscan2
- PRPF19 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 178/1309 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PRSS36 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 380/2350 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.019); called by muse, varscan2
- PSD3 | c.2240del p.K747Sfs*73 (on ENST00000440756; = p.K746Sfs*73 on NM_015310.4) | Frame Shift Del (DEL) | VAF 108/819 reads (13%) | called by mutect2, varscan2
- PSMB3 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 206/1522 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.04); called by muse, varscan2
- PTF1A | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 326/2071 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGR1 | c.101del p.N34Mfs*17 | Frame Shift Del (DEL) | VAF 121/810 reads (15%) | called by mutect2, pindel, varscan2
- PTPRG | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 220/1416 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 201/1046 reads (19%) | called by mutect2, varscan2
- R3HDM1 | c.466T>G p.F156V | Missense Mutation (SNP) | VAF 62/653 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- RABEP1 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 218/1334 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RAD54L | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 180/1275 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- RAPGEF2 | c.1564del p.S522Vfs*12 | Frame Shift Del (DEL) | VAF 203/1455 reads (14%) | called by mutect2, pindel, varscan2
- RASGRF2 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 161/1101 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- RASL10B | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 192/1133 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- RAVER1 | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 240/1618 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RBPJL | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 232/1525 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
447 further variants in this file (143 protein-altering or splice-affecting, 253 silent, 51 other) are not listed here.
